FM case AD47 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms.
https://portal.gdc.cancer.gov/cases/ce82c5cb-c93d-4005-b466-f25b053f0171

Male, 55.6 years: Myoepithelial carcinoma (ICD-O-3 8982/3); specimen biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Tumor.
